Somatic mutation profile of tumor specimen C3N-03073-02 (aliquot CPT0209100006) from CPTAC case C3N-03073, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.0 years (25,205 days).
Specimen C3N-03073-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e984791f-778c-4bfb-b604-a87c90d99d54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03073-31 (Blood Derived Normal), aliquot CPT0209150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57252dd3-61ce-46cb-93cd-60125f996bfc

The open-access MAF lists 191 somatic variants for this specimen: 125 protein-altering or splice-affecting, 43 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 43, Nonsense Mutation 10, Intron 8, Frame Shift Del 5, 5'UTR 5, Splice Site 4, 3'UTR 3, RNA 3, 5'Flank 2, In Frame Del 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 88/408 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 126/373 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 90/298 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3790C>T p.R1264* | Nonsense Mutation (SNP) | VAF 16/266 reads (6%) | hotspot (GDC flag); catalogued as rs1555039343, COSV63282990; ClinVar: pathogenic; called by muse, mutect2
- ADNP | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs758615541, COSV62426522; called by muse, mutect2, varscan2
- AL592490.1 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV69428128; called by muse, mutect2, varscan2
- ANKRD36C | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs745496346; called by muse, mutect2, varscan2
- ASXL3 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs768555015; called by muse, mutect2
- B3GNT7 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1396378590; called by muse, mutect2, varscan2
- CCER1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV62647275; called by muse, mutect2
- CDK7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99841871; called by muse, mutect2, varscan2
- CEMIP | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756591680; called by muse, mutect2
- CHD3 | c.3793G>C p.D1265H | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100391105; called by muse, mutect2, varscan2
- CNTNAP5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.709); catalogued as rs201163242, COSV70513494; called by muse, mutect2, varscan2
- CPNE3 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 46/220 reads (21%) | catalogued as rs778473378; called by muse, mutect2, varscan2
- CRAT | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV58879400; called by muse, mutect2, varscan2
- DDX51 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs927203771; called by muse, mutect2, varscan2
- DRC1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as rs754270018, COSV56537177; called by muse, mutect2, varscan2
- EFCAB3 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59502507; called by muse, mutect2, varscan2
- ELFN1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1444533304, COSV70034431; called by muse, mutect2
- FAM171A1 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs766395846; called by muse, mutect2, varscan2
- FKTN | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 62/236 reads (26%) | catalogued as COSV56311317; called by muse, mutect2, varscan2
- GLG1 | c.1663del p.R555Gfs*86 | Frame Shift Del (DEL) | VAF 85/334 reads (25%) | catalogued as COSV52667446, COSV99215712; called by mutect2, pindel, varscan2
- HOGA1 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as rs375261073; called by muse, mutect2, varscan2
- KANK1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs149974823; called by muse, mutect2, varscan2
- LCE2D | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 95/717 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV64229138; called by muse, mutect2, varscan2
- LRP1B | c.7802G>C p.G2601A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101250987, COSV67213525; called by muse, mutect2, varscan2
- MAGEC3 | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100024907; called by muse, mutect2, varscan2
- MS4A2 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1405540527; called by muse, mutect2, varscan2
- MYH2 | c.4366G>T p.D1456Y | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55432607; called by muse, mutect2, varscan2
- MYO9A | c.3566C>T p.S1189L | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.113); catalogued as COSV61849906; called by muse, mutect2, varscan2
- MYOD1 | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs747125822, COSV51453650; called by muse, mutect2, varscan2
- NKTR | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 40/160 reads (25%) | catalogued as COSV51769331; called by muse, mutect2, varscan2
- OR5T2 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs372162686; called by muse, mutect2, varscan2
- OTOGL | c.6922G>A p.E2308K (on ENST00000547103; = p.E2299K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV54013937; called by muse, mutect2, varscan2
- PBRM1 | c.4030C>A p.Q1344K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99969566; called by muse, mutect2, varscan2
- PCDHGA12 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV52754069; called by muse, mutect2, varscan2
- PSD4 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); catalogued as COSV55525966; called by muse, mutect2, varscan2
- RASGEF1C | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1039232521, COSV63178305; called by muse, mutect2
- RBMXL3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as rs782556433; called by muse, mutect2, varscan2
- SALL3 | c.1757C>A p.S586* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as rs1360494528; called by muse, mutect2, varscan2
- SEC16A | c.3089C>T p.S1030F | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.673); catalogued as COSV99256696; called by muse, mutect2, varscan2
- SHC1 | c.556C>G p.Q186E (on ENST00000368445 / NM_183001.5; = p.Q76E on NM_003029.5) | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100821073; called by muse, mutect2, varscan2
- SLITRK5 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs144076922, COSV100280998; called by muse, mutect2, varscan2
- SMC4 | c.3815_3817del p.T1272del | In Frame Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs755759095; called by mutect2, pindel, varscan2
- TCF20 | c.5054C>T p.S1685L | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs267606263, COSV59488860; called by muse, mutect2, varscan2
- TUBA1B | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV60137003, COSV60138363; called by muse, mutect2
- USH2A | c.5074G>T p.D1692Y | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV56397328; called by muse, mutect2, varscan2
- VSIR | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs746223877; called by muse, mutect2, varscan2
- ZNF234 | c.1924C>A p.H642N | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70602917; called by muse, mutect2, varscan2
- ACAN | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ACTL10 | c.459A>T p.K153N | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANAPC1 | c.5385+1_5385+3del p.X1795_splice | Splice Site (DEL) | VAF 16/90 reads (18%) | called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5645C>G p.S1882* | Nonsense Mutation (SNP) | VAF 76/282 reads (27%) | called by muse, mutect2, varscan2
- AP3S1 | c.6C>G p.I2M | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AREG | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 172/654 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- C3orf20 | c.976del p.R326Afs*110 | Frame Shift Del (DEL) | VAF 71/373 reads (19%) | called by mutect2, pindel, varscan2
- CCNDBP1 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CDC42BPG | c.2495C>G p.S832* | Nonsense Mutation (SNP) | VAF 127/495 reads (26%) | called by muse, mutect2, varscan2
- CLSTN3 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CNTN3 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND1 | c.1722+1_1722+5del p.X574_splice | Splice Site (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- EFCAB10 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EGLN1 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 83/496 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EIF3I | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EML2 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.014); called by muse, mutect2
- EPHA6 | c.2258C>T p.P753L (on ENST00000389672 / NM_001080448.3; = p.P145L on NM_173655.4) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- EVI5 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FSCN3 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2
- GGNBP2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GPA33 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 65/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRASP1 | c.3250G>A p.G1084S | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- HMBOX1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IGKV3-15 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 112/499 reads (22%) | called by muse, mutect2, varscan2
- IL15 | c.379-1G>C p.X127_splice | Splice Site (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- KANK1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KLRG2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRC3C | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MAP3K4 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MIA3 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MN1 | c.1666C>G p.L556V | Missense Mutation (SNP) | VAF 110/368 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); called by muse, varscan2
- MON2 | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- MTRNR2L6 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 79/212 reads (37%) | PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MUC12 | c.14563A>T p.T4855S (on ENST00000379442; = p.T4712S on NM_001164462.1) | Missense Mutation (SNP) | VAF 171/596 reads (29%) | SIFT tolerated, low confidence (0.16); called by muse, mutect2, varscan2
- NBEAL2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPH | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIPBL | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- NPHP3 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OBSCN | c.21292A>T p.M7098L | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAF1 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 125/506 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PANK4 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- PCDH11Y | c.1563T>A p.S521R (on ENST00000400457 / NM_032973.2; = p.S510R on NM_032971.3) | Missense Mutation (SNP) | VAF 195/296 reads (66%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZRN4 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEAK1 | c.4724C>G p.S1575C | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLK1 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- POM121L2 | c.2383G>T p.V795F | Missense Mutation (SNP) | VAF 139/534 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPCS | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2
- PRPF8 | c.3651G>C p.Q1217H | Missense Mutation (SNP) | VAF 101/471 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSMC4 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- PTPN4 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2777C>G p.S926C | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBCK1 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SCN3A | c.3857G>T p.S1286I | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SCYL3 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- SETD1B | c.3835del p.A1279Pfs*37 | Frame Shift Del (DEL) | VAF 184/489 reads (38%) | called by mutect2, pindel, varscan2
- SETD2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- SHROOM3 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 139/485 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SLC38A7 | c.134del p.G45Vfs*82 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNTG2 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTBN5 | c.4816_4817del p.G1606Pfs*10 | Frame Shift Del (DEL) | VAF 149/643 reads (23%) | called by mutect2, pindel, varscan2
- TIMM13 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- TNFSF13 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TOM1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 92/325 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- TRDN | c.996dup p.E333Rfs*8 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- TRPM1 | c.4146T>A p.N1382K | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); called by muse, mutect2
- UQCRB | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- VENTX | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VTCN1 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- VWA2 | c.1550dup p.C518Vfs*45 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- ZNF335 | c.2073_2075del p.K691del | In Frame Del (DEL) | VAF 6/37 reads (16%) | called by pindel, varscan2
- ZNF624 | c.1298T>A p.V433E | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ZNF708 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.063); called by muse, mutect2
- ZNF837 | c.1405C>G p.H469D | Missense Mutation (SNP) | VAF 88/493 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZSWIM2 | c.1775A>T p.K592I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- AHCTF1 | c.1917A>G p.P639= (on ENST00000366508; = p.P613= on NM_015446.5) | Silent (SNP) | VAF 108/336 reads (32%) | catalogued as rs373043560; called by muse, mutect2, varscan2
- AMPH | c.1203T>C p.N401= | Silent (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- ANKEF1 | c.459C>T p.F153= | Silent (SNP) | VAF 71/321 reads (22%) | catalogued as COSV101001023; called by muse, mutect2, varscan2
- C6orf120 | c.18G>A p.G6= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs909167890; called by muse, mutect2, varscan2
- CACNA2D3 | c.2418C>T p.L806= | Silent (SNP) | VAF 41/223 reads (18%) | catalogued as COSV99878157; called by muse, mutect2, varscan2
- CBLB | c.429C>T p.L143= | Silent (SNP) | VAF 60/253 reads (24%) | catalogued as rs116460400; called by muse, mutect2, varscan2
- CDC45 | c.21C>T p.R7= | Silent (SNP) | VAF 77/340 reads (23%) | called by muse, mutect2, varscan2
- CHST8 | c.495C>T p.A165= | Silent (SNP) | VAF 15/521 reads (3%) | catalogued as rs1173742376; called by muse, mutect2
- CLDN3 | c.396C>T p.L132= | Silent (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- CLN8 | c.27A>G p.T9= | Silent (SNP) | VAF 88/196 reads (45%) | catalogued as rs750274455; called by muse, mutect2, varscan2
- CRACR2A | c.424C>T p.L142= | Silent (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- CSMD3 | c.6045C>A p.P2015= (on ENST00000297405 / NM_001363185.1; = p.P1911= on NM_052900.3) | Silent (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- DCSTAMP | c.1164G>A p.V388= | Silent (SNP) | VAF 74/324 reads (23%) | catalogued as rs752581420; called by muse, mutect2, varscan2
- ENTPD8 | c.645C>T p.F215= | Silent (SNP) | VAF 60/225 reads (27%) | catalogued as rs367913136; called by muse, mutect2, varscan2
- EPHA5 | c.204T>A p.T68= | Silent (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- FREM3 | c.5769C>T p.S1923= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- GOLGB1 | c.8277G>A p.R2759= | Silent (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- GRM8 | c.2415C>A p.A805= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100281513; called by muse, mutect2, varscan2
- GTF3C1 | c.168C>T p.G56= | Silent (SNP) | VAF 81/268 reads (30%) | called by muse, mutect2, varscan2
- INIP | c.204G>A p.Q68= | Silent (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- LAMC1 | c.4296C>T p.I1432= | Silent (SNP) | VAF 73/396 reads (18%) | catalogued as rs1358421918, COSV51132330; called by muse, mutect2, varscan2
- LIN54 | c.1024C>T p.L342= | Silent (SNP) | VAF 53/269 reads (20%) | called by muse, mutect2, varscan2
- MAP2 | c.2364T>G p.S788= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- MVB12A | c.579G>A p.R193= | Silent (SNP) | VAF 75/307 reads (24%) | called by muse, mutect2, varscan2
- NOL10 | c.1242G>T p.L414= | Silent (SNP) | VAF 44/140 reads (31%) | called by muse, mutect2, varscan2
- NR4A3 | c.567G>T p.P189= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs897620552; called by muse, mutect2, varscan2
- OR51T1 | c.666G>A p.L222= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV59028419; called by muse, mutect2, varscan2
- OTOP3 | c.1599G>T p.P533= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- PLCE1 | c.5589G>A p.L1863= | Silent (SNP) | VAF 74/288 reads (26%) | called by muse, mutect2, varscan2
- PLK5 | c.678G>A p.T226= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs755084609; called by muse, mutect2, varscan2
- PTPRO | c.2475G>T p.V825= | Silent (SNP) | VAF 108/235 reads (46%) | called by muse, mutect2, varscan2
- RPIA | c.615C>T p.L205= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as rs1440733627, COSV52168158; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL9 | c.2682T>C p.S894= | Silent (SNP) | VAF 97/377 reads (26%) | called by muse, mutect2, varscan2
- SCAPER | c.1926A>G p.L642= | Silent (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- SGK1 | c.945G>A p.Q315= | Silent (SNP) | VAF 74/264 reads (28%) | called by muse, varscan2
- TFCP2 | c.195G>T p.L65= | Silent (SNP) | VAF 66/222 reads (30%) | called by muse, mutect2, varscan2
- TLR9 | c.1209C>T p.I403= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- TMEM39B | c.174C>G p.T58= | Silent (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- TRPV5 | c.1758C>A p.A586= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- TUB | c.273C>A p.L91= (on ENST00000299506 / NM_177972.3; = p.L146= on NM_003320.4) | Silent (SNP) | VAF 133/368 reads (36%) | called by muse, mutect2, varscan2
- VPS51 | c.372G>A p.K124= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- ZBED1 | c.1116C>T p.A372= | Silent (SNP) | VAF 24/612 reads (4%) | catalogued as rs370706648; called by muse, mutect2
- ZNF837 | c.1443C>G p.G481= | Silent (SNP) | VAF 85/491 reads (17%) | called by muse, mutect2, varscan2
- AQP1 | c.*289C>G | 3'UTR (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915303 G>T | 5'Flank (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- CCDC61 | c.762+30G>A | Intron (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2, varscan2
- CERS3 | c.-1-1863C>A | Intron (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
- CFAP94 | c.89-164G>C | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- DAZAP2 | c.-31G>A | 5'UTR (SNP) | VAF 73/430 reads (17%) | called by muse, mutect2, varscan2
- LINC02870 | n.281C>T | RNA (SNP) | VAF 124/305 reads (41%) | called by muse, mutect2, varscan2
- LRRC37A4P | n.5099A>G | RNA (SNP) | VAF 75/286 reads (26%) | called by muse, mutect2, varscan2
- MGAM | c.4619-204T>G | Intron (SNP) | VAF 250/722 reads (35%) | called by muse, mutect2, varscan2
- MOV10L1 | c.97+52C>G | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- MRPL13 | c.393+34C>T | Intron (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- MRPL27 | c.-6G>C | 5'UTR (SNP) | VAF 62/339 reads (18%) | called by muse, mutect2, varscan2
- NMT2 | c.*3166G>C | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- OR7E5P | n.531C>G | RNA (SNP) | VAF 75/379 reads (20%) | called by muse, mutect2, varscan2
- POU2F2 | c.*140G>A | 3'UTR (SNP) | VAF 171/372 reads (46%) | called by muse, mutect2, varscan2
- RAD17 | chr5:69371151 G>T | 5'Flank (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- SATL1 | c.-479G>T | 5'UTR (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- SECISBP2 | chr9:89363437 T>G | 3'Flank (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- SH3GLB2 | c.562-707G>C | Intron (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- TMEM199 | c.212-471G>T | Intron (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49972669 C>A | 3'Flank (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- ZNF57 | c.-43G>C | 5'UTR (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- ZNF875 | c.-245C>T | 5'UTR (SNP) | VAF 64/296 reads (22%) | called by muse, mutect2, varscan2
